Somatic mutation profile of tumor specimen 0DHX36 from CCDI case PBBUKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 10.3 years (3,776 days).
Specimen 0DHX36: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3b074c1-3138-49b2-9e90-8766ac83e6b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHX1V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2cdc199-3794-4207-8d9d-16e553348397

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Frame Shift Del 5, Intron 2, 5'UTR 2, Nonsense Mutation 1, In Frame Ins 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD3 | c.3563C>G p.A1188G | Missense Mutation (SNP) | VAF 133/451 reads (29%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.988); catalogued as rs769694017, COSV57873204, COSV57874208; called by muse, mutect2, varscan2
- FRK | c.295T>A p.Y99N | Missense Mutation (SNP) | VAF 132/407 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74177344; called by muse, mutect2, varscan2
- PCDHGB3 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53895008; called by muse, mutect2, varscan2
- RERE | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 165/299 reads (55%) | catalogued as COSV100556997; called by muse, mutect2, varscan2
- BCORL1 | c.2719A>G p.T907A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CR2 | c.2369A>T p.N790I | Missense Mutation (SNP) | VAF 103/384 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- EIF4A1 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 91/350 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HEATR5A | c.4106T>C p.L1369S | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ITSN2 | c.1573_1580del p.V525* | Frame Shift Del (DEL) | VAF 140/506 reads (28%) | called by mutect2, varscan2
- LGALS3BP | c.432_435del p.Q145Sfs*14 | Frame Shift Del (DEL) | VAF 85/298 reads (29%) | called by mutect2, varscan2
- NR2C2 | c.711_720del p.G238Ifs*6 (on ENST00000393102; = p.G257Ifs*6 on NM_003298.5) | Frame Shift Del (DEL) | VAF 86/388 reads (22%) | called by mutect2, varscan2
- PDGFRA | c.1470_1471insCACTTGACTTTC p.F490_A491insHLTF | In Frame Ins (INS) | VAF 87/312 reads (28%) | called by mutect2, varscan2
- PTGS1 | c.1511del p.P504Lfs*18 | Frame Shift Del (DEL) | VAF 90/264 reads (34%) | called by mutect2, varscan2
- SLC25A48 | c.958_961del p.P320Tfs*36 | Frame Shift Del (DEL) | VAF 132/216 reads (61%) | called by mutect2, varscan2
- SMCR8 | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 133/311 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- TPD52L2 | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.85); called by mutect2, varscan2
- AGAP2 | c.1014C>T p.S338= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, varscan2
- ADGRG6 | c.1069+70G>A | Intron (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- AMPD2 | c.1699-34C>A | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, varscan2
- EXPH5 | c.-212C>G | 5'UTR (SNP) | VAF 99/412 reads (24%) | called by muse, mutect2, varscan2
- GSDMC | c.*4C>A | 3'UTR (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2
- IL17REL | c.-36A>C | 5'UTR (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
